Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5457, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5457-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA-CZ-5457

***** Addended Report *****

PATHOLOGIC DIAGNOSIS:

A. RIGHT KIDNEY, NEPHRECTOMY:

RENAL CELL CARCINOMA (13.5 cm), clear cell, Fuhrman grade IV (of IV), arising in the right lower pole.

The tumor extends into the perirenal adipose tissue.

Lymphovascular invasion is identified.

Tumor invades the renal parenchyma and renal pelvis and renal sinus.

Ureter, renal artery and vein margins are negative for tumor.

Colloidal iron is negative in the tumor cells.

Immunohistochemistry performed at BWH demonstrates the following staining profile in tumor cells:

Positive - CD10, RCC

AJCC Classification (6th Edition): T3a NX MX.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

B. REGIONAL LYMPH NODES:

Fibroadipose tissue and blood clot.

No lymph nodes are present (the entire specimen was examined).

CLINICAL DATA:

History: [REDACTED] with right kidney mass.

Operation: Nephrectomy.

Operative Findings: None given.

Clinical Diagnosis: None given.

ORGAN/TISSUE SUBMITTED:

A/1. Right kidney.

B/2. Regional lymph nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "#1. Right kidney", consists of a 1369-g right nephrectomy specimen (27.0 x 14.0 x 8.8 cm) including right kidney (18.8 x 8.0 x 8.0 cm) with a bifurcating renal artery (3.2 x 0.3 cm in diameter), renal vein (0.6 x 0.8 cm in diameter), and ureter (4.8 x 0.4 cm in diameter). No adrenal gland is grossly identified. The specimen is inked black and bivalved to reveal a tan-to-red to tan-to-yellow focally encapsulated, and hemorrhagic lobulated mass (13.5 x 10.0 x 10.5 cm) that is present in the lower pole of the kidney and directly abuts the capsule. The mass is less than 0.1 cm to the ink, 4.5 cm to the vein, 6.0 cm to the artery, and 6.5 cm to the ureter. Upon sectioning, the remainder of the kidney, there are multiple (greater than five) areas of red/brown nodularity (0.3 to 1.1 cm in greatest dimension) scattered throughout the renal parenchyma. There is also a large necrotic area (7.2 x

[page 2 of 3]
Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

PATIENT: [REDACTED]

Cytogenetics

CGA-CZ-5457

KARYOTYPE:

K3:70-80<4n>XXYY,-1,-3,-3,-8,-8,del(9)(p272)x2,-10,-10-14,-14,add(19)(q13)x2,+20,-21,-21,-22,-22[cp5]

METAPHASES COUNTED: 5 ANALYZED: 5 SCORED: 0 BANDING: GTG

INTERPRETATION:

Four different specimens were received from this tumor.

All metaphases from the specimen labeled T3 contained clonal aberrations that included loss of chromosome 3, a characteristic finding in renal cell carcinoma, clear cell type.

No metaphases were available from the remaining 3 specimens.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? Renal Cell Carcinoma

[REDACTED]

[page 3 of 3]
Pathology Report

The sample consists of cortex and medulla. There are two hundred-two (202) glomeruli present, of which 15 (7.4 %) are globally sclerosed; the sclerosed glomeruli tend to be grouped in small areas of parenchymal atrophy. The remaining glomeruli show significant expansion of the mesangial areas with focal formation of early nodules. There are no discernible craters or double contours of the glomerular capillary wall in the Jones' stain. Several distal tubules contain PAS-positive hyaline casts. The interstitium contains a mild mononuclear cell inflammatory infiltrate in areas of tubular atrophy. Approximately 30% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a moderate degree of sclerosis with hyaline degeneration.

Source: NCI Genomic Data Commons file 89c44bb5-3da6-42aa-8221-2a6719f16084 (TCGA-CZ-5457.3689C7B9-F39E-4533-A986-1E215F1CDB91.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).